Gene-level copy-number profile of tumor specimen TARGET-10-PASPBU-09A from TARGET case TARGET-10-PASPBU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,673 days).
Specimen TARGET-10-PASPBU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.6daba828-4527-5ca3-8e5c-a3d11c445213.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASPBU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate.
https://portal.gdc.cancer.gov/files/a3048613-d5c9-4a6e-92f2-533959686290

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 3,343; copy number 2: 55,316; copy number 3: 1,542.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,708,125–29,708,547, 1 gene: ZDHHC20P1.
- chr7:38,239,580–38,340,998, 17 genes: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes: TRGV5P, TRGV5.
- chr9:37,422,666–37,436,990, 1 gene (within-gene range 0–1): GRHPR.
- chr14:21,852,558–21,853,006, 1 gene: TRAV8-3.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 956. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
